Surgical pathology report (de-identified scan), TCGA case TCGA-CR-7372, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Vanderbilt University, specimen TCGA-CR-7372-01A (Primary Tumor).

[page 1 of 4]
Accession number: [REDACTED]

Final Report

DIAGNOSIS:

- 1) MOUTH, ANTERIOR FLOOR, MARGIN, EXCISION: SQUAMOUS MUCOSA, NEGATIVE FOR MALIGNANCY.
- 2) MOUTH, POSTERIOR FLOOR, MARGIN, EXCISION: SQUAMOUS MUCOSA AND SALIVARY GLAND, NEGATIVE FOR MALIGNANCY.
- 3) TONGUE, ANTERIOR MARGIN, EXCISION: SQUAMOUS MUCOSA, NEGATIVE FOR MALIGNANCY.
- 4) TONGUE, POSTERIOR MARGIN, EXCISION: SQUAMOUS MUCOSA, NEGATIVE FOR MALIGNANCY.
- 5) TONGUE, "CANCER," LEFT, EXCISION: WELL-DIFFERENTIATED INVASIVE SQUAMOUS CELL CARCINOMA, 1.5 CM IN GREATEST EXTENT, 0.7 CM TO DEEP MARGIN, NEGATIVE FOR LYMPHOVASCULAR INVASION AND PERINEURAL INVASION, SALIVARY GLAND, NEGATIVE FOR MALIGNANCY (SEE COMMENT).
- 6) LYMPH NODES, LEFT NECK LEVEL 2-3, EXCISION: 18 LYMPH NODES, NEGATIVE FOR MALIGNANCY (0/18).
- 7) LYMPH NODE, LEFT NECK LEVEL 1B, EXCISION: SALIVARY GLAND, NEGATIVE FOR MALIGNANCY; 1 LYMPH NODE, NEGATIVE FOR MALIGNANCY (0/1).

COMMENT: These findings correspond to AJCC 6th edition pathologic stage I (pT1N0M n/a).

Upper Aerodigestive Tract and Minor Salivary Glands Carcinoma

Summary of Findings:

Specimen Type: excision

Tumor Site: tongue

Tumor Size: 1.5 x 1.5 x 0.3 cm

Histologic Type: squamous cell carcinoma

Histologic Grade: well differentiated

Pathologic Staging (pTMN) I

Primary tumor (pT): pT1

Regional Lymph Nodes (pN): pN0 (0/19)

Number examined: 19

[REDACTED]

[page 2 of 4]
Numbered involved: 0

Extracapsular extension: No

Perineural invasion: (Select one)

☒ No

☐ Not evaluable

Bony/Cartilage Invasion: (Select one) Yes

☒ No

☐ Not evaluable

HPV testing ordered: Yes (performed on oral cavity and oropharyngeal squamous cell carcinomas) (block 5E).

**Electronically

CLINICAL DATA

Clinical Features: Unspecified

Operator:

Operation: Unspecified

Operative Findings: Unspecified

Operative Diagnosis: Unspecified

Tissue Submitted: 1) anterior floor of mouth margin; 2) posterior floor of mouth margin; 3) anterior tongue margin; 4) posterior tongue margin; 5) L tongue cancer; 6) L neck dissection level 2-3; 7) L neck dissection level 1B

GROSS DESCRIPTION:

1) SOURCE: Anterior Floor of Mouth Margin

Received fresh for frozen section labeled "anterior floor of mouth margin" is a fragment of pink-white mucosal tissue that is 2.5 x 0.5 x 0.5 cm. The specimen is submitted for frozen section and entirely resubmitted.

Summary of sections: 1AFSC, 1/1.

2) SOURCE: Posterior Floor of Mouth Margin

Received fresh for frozen section labeled "posterior floor of mouth margin" is a fragment of white-pink mucosal tissue that is 2.3 x 1.0 x 0.3 cm. The specimen is submitted for frozen section and entirely resubmitted.

Summary of sections: 2AFSC, 1/1.

3) SOURCE: Anterior Tongue Margin

Received fresh for frozen section labeled "anterior tongue margin" is a fragment of white-pink soft tissue that is 4.7 x 0.5 x 0.9 cm. The specimen is submitted for frozen section and entirely resubmitted.

[page 3 of 4]
Summary of sections: 3AFSC, 1/1.

4) SOURCE: Posterior Tongue Margin

Received fresh for frozen section labeled "posterior tongue margin" is a fragment of white-pink, gritty soft tissue that is 3.7 x 0.5 x 0.3 cm. The specimen is entirely submitted for frozen section and entirely resubmitted.

Summary of sections: 4AFSC, 2/1.

5) SOURCE: Left Tongue Cancer

Received fresh labeled "left tongue cancer, 1 stitch = anterior; 2 stitches = medial" is a resection of tongue that is 3.5 x 3.5 x 2.0 cm. The tongue shows a centrally located pink-red, hemorrhagic ulcer that is 1.5 x 1.5 in area x 1.0 cm in depth. The specimen is inked as follows: anterior = yellow, medial = blue, lateral = green, posterior = orange, deep = black.

The surface is pink-tan, mildly edematous and otherwise unremarkable.

Serial sectioning from medial to lateral reveals a well-circumscribed, white ulcer extends 0.3 cm in depth and is 1.5 cm to medial, 1.2 cm to lateral, 0.9 cm to anterior, 1.3 cm to posterior, and 0.7 cm to deep.

Representative sections are submitted. The ulcer is entirely submitted.

Summary of sections: 5A, medial margin in cross section, M/1; 5B, lateral margin cross section, M/1; 5C, ulcer level 1 and posterior margin, 2/1; 5D, ulcer and posterior-deep margin, 2/1; 5E-F, ulcer and posterior margin, 1/1 each; 5G-H, ulcer and posterior margin, 1/1 each.

6) SOURCE: Left Neck Dissection Level 2-3

Received fresh labeled "left neck dissection levels 2-3" is a fragment of fibrofatty tissue that is 5.0 x 3.5 x 2.0 cm. A search for lymph nodes reveals multiple lymph nodes ranging in size from 0.5 to 2.5 cm in greatest extent.

Summary of sections: 6A-B, 1 lymph node serially sectioned, 3/1; each; 6C, multiple nodes, M/1; 6D, multiple nodes, M/1; 6E, 2 nodes bisected, 1 inked blue, 4/1.

7) SOURCE: Left Neck Dissection Level 1B

Received fresh labeled "left neck level 1B" is a fragment of fibrofatty tissue that is 5.0 x 3.0 x 3.0 cm. A search for lymph nodes reveals multiple possible lymph nodes ranging in size from 0.2 to 0.4 cm in greatest extent. A portion of lobulated yellow-white tissue consistent with a salivary gland is present measuring approximately 2.5 x 2.0 x 1.5 cm. Representative sections of the possible salivary gland and all lymph nodes identified are submitted.

Summary of sections: 7A, 3 sections of possible salivary gland and possible nodes, M/1; 7B-C, node candidates, M/1.

[page 4 of 4]
1) SOURCE: Anterior Floor of Mouth Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

2) SOURCE: Posterior Floor of Mouth Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

3) SOURCE: Anterior Tongue Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

4) SOURCE: Posterior Tongue Margin

FROZEN SECTION DIAGNOSIS: NEGATIVE FOR TUMOR. [REDACTED]

Electronically signed by: [REDACTED]

[REDACTED]

The following report contains additional information regarding HPV analyses that supplements the previously issued report.

ADDENDUM FINDINGS:

HPV studies as performed by [REDACTED]
[REDACTED] laboratories show the tumor cells to be p16 negative by immunohistochemistry and HPV negative by in situ hybridization.

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 28a78281-ce63-445a-83f8-8163b45f0133 (TCGA-CR-7372.9D76168F-3534-4CDF-8B1E-A72FD4DFF4A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).